Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A12A, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A12A-01A (Primary Tumor).

[page 1 of 7]
ductal carcinoma, poorly differentiated. Now for TM sw.

2: SP: Sentinel node #1 level one

- 3: SP: Sentinel node #2 level one right axilla
- 4: SP: Sentinel node #3 level one right axilla
- 5: SP: Sentinel node #4 level one right axilla
- 6: SP: Non-sentinel tissue right axilla
- 7: SP: Sentinel node #5 level one right axilla
- 8: SP: Additional superior right mastectomy flap

1) BREAST, RIGHT AND SILICONE IMPLANT; MASTECTOMY;
- INVASIVE DUCTAL CARCINOMA, HISTOLOGIC CR.

- DUCTAL CARCINOMA IN SITU (DCIS) IS ALSO IDENTIFIED, SOLID AND
CRIBRIFORM TYPES WITH INTERMEDIATE TO HIGH NUCLEAR GRADE AND MINIMAL
NECROSIS. THE DCIS CONSTITUTES <= 25% OF THE TOTAL TUMOR MASS, AND IS
PRESENT ADJACENT WITH THE INVASIVE COMPONENT.
- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER OUTER QUADRANT. THE
DCIS IS LOCATED IN THE UPPER OUTER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN SITU OR INVASIVE CARCINOMA
IS IDENTIFIED.

- NO CALCIFICATIONS ARE IDENTIFIED IN EITHER THE INVASIVE OR IN SITU CARCINOMA.
- NO VASCULAR INVASION IS NOTED.
- NO INVOLVEMENT OF THE SURGICAL MARGINS BY EITHER INVASIVE OR IN SITU CARCINOMA IS IDENTIFIED.
- INVASIVE CARCINOMA IS 0.2 CM FROM THE NEAREST (ANTERIOR AND DEEP) MARGINS.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES AND FIBROCYTIC CHANGES WITH APOCRINE METAPLASIA, MICROCALCIFICATIONS, AND COLUMNAR CELL ALTERATION WITHOUT ATYPIA.

PATH
REPORT

ICD-0-3
carcinoma, infiltrating duct, NOS 8500/3
Site: breast, NOS C50.9 (w)
10/22/11

	Yes	No
Cite's		
Literature discrepancy		
Physical location discrepancy		
DIPN discrepancy		
Patient history discrepancy		
Drugs/Symptoms/Prognosis history		
Cite's notes		
Letter verification		

(Handwritten signatures and initials are present over the table rows)

DISCOUNTED
two + 9/2-2-11

[page 2 of 7]
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

- 2) LYMPH NODE, SENTINEL #1, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1). DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 3) LYMPH NODE, SENTINEL #2, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1). DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 4) LYMPH NODE, SENTINEL #3, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1). DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 5) LYMPH NODE, SENTINEL #4, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE BENIGN LYMPH NODE (0/1). DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 6) NON-SENTINEL TISSUE, RIGHT AXILLA; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 7) LYMPH NODES, SENTINEL #5, LEVEL I, RIGHT AXILLA; EXCISION:
- TWO BENIGN LYMPH NODES (0/2). DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED. THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 8) BREAST, RIGHT, ADDITIONAL SUPERIOR MASTECTOMY FLAP TISSUE; EXCISION:
- BENIGN FIBROADIPOSE TISSUE AND SKELETAL MUSCLE.
- NO RESIDUAL CARCINOMA SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

MD/

*** Report Electronically Signed Out ***

Special Studies:

Result	Special Stain	Comment
positive	ER-C	
positive	PR-C	
negative	HER2-C	
	NEG CONT	intensity of 1+
	NEG-HER2	
negative	IMM RECUT	
	AE1:AE3	
	NEG CONT	
positive	IMM RECUT	
	AE1:AE3	
	NEG CONT	
negative	IMM RECUT	
	AE1:AE3	
	NEG CONT	

PATH
REPORT

** Continued on next page **

[page 3 of 7]
negative

IMM RECUT
AE1:AE3
NEG CONT
IMM RECUT
AE1:AE3
NEG CONT
IMM RECUT

negative

3

Gross Description:

1) The specimen is received fresh, labeled, "Right breast and silicone implant". It consists of product of right mastectomy which measures 14.0 cm from superior to inferior, 14.0 cm from medial to lateral, 5.0 cm from anterior to posterior. There is a skin ellipse with nipple areolar complex which measures 10.0 x 3.5 cm. The nipple is erect. The posterior aspect is inked in black, superior-anterior tissue edge is inked in green, and the inferior-anterior tissue edge is inked in blue. The specimen is serially sectioned from the lateral to medial revealing a stellate vasculated mass in the upper outer quadrant which measures 3.1 x 1.4 x 1.7 cm. It is present 0.2 cm from anterior tissue edge, 0.2 cm from the deep surgical margin. The deep margin is easily movable over the tumor mass. A silicone implant is identified which measures 7.0 x 7.0 x 0.3 cm. It is intact. It is surrounded by fibrous partially calcified capsule.

Summary of Sections:

N nipple
T tumor
UOQ - upper outer quadrant
LOQ - lower outer quadrant
UIQ - upper inner quadrant
LIQ - lower inner quadrant

2) The specimen is received fresh for frozen section, labeled "Sentinel node #1 level one right axilla". It consists of one firm brown-tan node measuring 1.0 x 0.5 x 0.4 cm. Bisected and entirely frozen.

Summary of Sections:

FSC - frozen section control

3) The specimen is received fresh for frozen section, labeled "Sentinel node #2 level one right axilla". It consists of a 1.6 x 1.2 x 0.6 cm brown-tan lymph node bisected and entirely frozen.

Summary of Sections:

FSC - frozen section control

PATH
REPORT

** Continued on next page **

[page 4 of 7]
4) The specimen is received fresh for frozen section, labeled "Sentinel node #3 level one right axilla". It consists of a 1.7 x 0.6 x 0.6 cm brown-tan node bisected and entirely frozen.

Summary of Sections:
FSC - frozen section control

5) The specimen is received in formalin, labeled "Sentinel node #4 level one right axilla". It consists of a portion of adipose tissue which measures 1.9 x 1.5 x 0.6 cm. Examination reveals a pink-tan lymph node which measures 1.5 x 1.0 x 0.4 cm. The lymph node is bisected and submitted entirely.

Summary of Sections:
SN sentinel node

6) The specimen is received in formalin, labeled "Non-sentinel tissue right axilla". It consists of three irregular shaped portions of yellow adipose which measures 0.6 x 2.5 cm in greatest dimension. The specimen is submitted entirely in one cassette.

Summary of Sections:
NS non-sentinel tissue

7) The specimen is received in formalin, labeled "Sentinel node #5 level one right axilla". It consists of pink-tan portion of soft tissue which measures 0.7 x 0.4 x 0.3 cm. The specimen is submitted entirely.

Summary of Sections:
SN sentinel node

8) The specimen is received in formalin, labeled "Additional superior right mastectomy flap tissue". It consists of two unoriented flap portions of fibrofatty tissue which measure 5.5 x 2.0 x 0.6 cm and 4.5 x 3.0 x 0.9 cm. Each piece has a cauterized aspect which is inked in red. The opposing aspect is inked in green. The specimen is serially sectioned and submitted entirely.

Summary of Sections:
U - undesignated

PATH
REPORT

** Continued on next page **

[page 5 of 7]
Summary of Sections:

Part 1: SP: Right breast and silicone implant

Block	Sect.	Site	PCs
1		C	
1		LIQ	3
1		LOQ	1
1		N	1
5		T	5
1		UIQ	1

Part 2: SP: Sentinel node #1 level one right axilla

Block	Sect.	Site	PCs
1		FSC	1

Part 3: SP: Sentinel node #2 level one right axilla

Block	Sect.	Site	PCs
1		FSC	1

Part 4: SP: Sentinel node #3 level one right axilla

Block	Sect.	Site	PCs
1		FSC	1

Part 5: SP: Sentinel node #4 level one right axilla

Block	Sect.	Site	PCs
1		SN	1

Part 6: SP: Non-sentinel tissue right axilla

Block	Sect.	Site	PCs
1		NS	1

Part 7: SP: Sentinel node #5 level one right axilla

Block	Sect.	Site	PCs
1		SN	1

Part 8: SP: Additional superior right mastectomy flap tissue

Block	Sect.	Site	PCs
8		U	8

Procedures/Addenda:

Addendum

Date Ordered:

Date Complete:

Status: Signed Out

By:

PATH
REPORT

** Continued on next page **

[page 6 of 7]
Date Reported:

Page 6 of 7

Addendum Diagnosis
ADDENDUM

SITE: SENTINEL LYMPH NODE, RIGHT AXILLA
PART #3.

METASTATIC CARCINOMA IN THE FORM OF MICROSCOPIC CLUSTERS, MEASURING LESS THAN 2MM (MICROMETASTASIS), IS IDENTIFIED ON ADDITIONAL H&E STAINED SECTIONS AND CYTOKERATIN IMMUNOHISTOCHEMICAL STAINS.

ADDITIONAL H&E STAINED SECTIONS AND IMMUNOHISTOCHEMICAL STAINS FOR CYTOKERATINS (AE1:AE3 AND CAM 5.2) ON THE OTHER SENTINEL LYMPH NODE FROM PART #2,4,5,7 SHOW NO EVIDENCE OF METASTATIC TUMOR.

Addendum

Date Ordered:

Date Complete:

Date Reported:

Status: Signed Out

By:

Addendum Diagnosis
ADDENDUM

SITE: RIGHT BREAST
PART #1.

ER: 90% OF NUCLEAR STAINING WITH MODERATE INTENSITY.

PR: 90% OF NUCLEAR STAINING WITH STRONG INTENSITY.

HER2/NEU (HERCEPT): NEGATIVE (STAINING INTENSITY OF 1+).

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 2) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES.
PATH
REPORT

** Continued on next page **

[page 7 of 7]
PERMANENT DIAGNOSIS: SAME.

- 3) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES.
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: BENIGN LYMPH NODES.
PERMANENT DIAGNOSIS: SAME.

71

** End of Report **

PATH
REPORT

Source: NCI Genomic Data Commons file e8524ef7-341e-42ab-9c1f-946afab0d57a (TCGA-AO-A12A.A54E82A4-D7C2-4A5C-A69C-C66976F0282F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).